MMRF case MMRF_1323 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/81f289f0-570f-4462-877d-2d2f16367ea0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 73.6 years (26,865 days); ISS stage: II; Days to last known disease status: 1,455 days (4.0 years); Days to last follow up: 1,455 days (4.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 77 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 20 days; Days to treatment end: 77 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 117 days; Days to treatment end: 117 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 117 days; Days to treatment end: 117 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 230 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -16: M Protein 2.58 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 2.76 g/L; Immunoglobulin A 34 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 4.06 µg/mL; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.09 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.38 mmol/L; Albumin 33 g/L; Total Protein 8.7 g/dL; Glucose 5.01 mmol/L; C-Reactive Protein 0.138 mg/dL.
- Day 62: M Protein 0.52 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 2.8 g/L; Immunoglobulin A 2.16 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 2.81 µg/mL; Hemoglobin 7.07 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.54 ×10⁹/L; Platelets 308 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.23 mmol/L.
- Day 153 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.08 mg/dL; Immunoglobulin G 3.18 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.52 µg/mL; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 11 ×10⁹/L; Absolute Neutrophil 6.93 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.48 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.89 mmol/L.
- Day 265 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 5.07 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.56 g/L; Beta 2 Microglobulin 2.76 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.62 ×10⁹/L; Platelets 276 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.5 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 5.61 mmol/L.
- Day 356 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 4.97 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 3.72 µg/mL; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.48 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 4.73 mmol/L.
- Day 447 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 5.41 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 3.11 µg/mL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 5.01 mmol/L.
- Day 503 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 6.03 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 2.71 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.29 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.48 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 4.62 mmol/L.
- Day 615 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 5.99 g/L; Immunoglobulin A 1.06 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 3.52 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.47 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.06 mmol/L.
- Day 671 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 5.58 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 3.06 µg/mL; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.92 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 4.35 mmol/L.
- Day 783 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.63 mg/dL; Immunoglobulin G 5.28 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.68 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.12 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.43 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 5.01 mmol/L.
- Day 867 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 5.72 g/L; Immunoglobulin A 1.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.51 µg/mL; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.92 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 4.79 mmol/L.
- Day 979 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.78 mg/dL; Immunoglobulin G 6.12 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.38 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.72 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 5.06 mmol/L.
- Day 1,091: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.99 mg/dL; Immunoglobulin G 5.36 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.56 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 5.61 mmol/L.
- Day 1,147: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.97 mg/dL; Immunoglobulin G 5.68 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 1.82 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.55 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.12 mmol/L.
- Day 1,259 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 4.89 g/L; Immunoglobulin A 1.51 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.72 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 4.24 mmol/L.
- Day 1,371: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 5.14 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2.33 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.28 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 4.84 mmol/L.
- Day 1,455: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.75 mg/dL; Immunoglobulin G 5.15 g/L; Immunoglobulin A 1.49 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.51 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 4.18 mmol/L.

Other clinical attributes
- Day -16: Weight: 93 kg; Height: 164 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1323_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -16 days.
- Sample MMRF_1323_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -16 days.
